Somatic mutation profile of tumor specimen TCGA-24-0966-01A (aliquot TCGA-24-0966-01A-01W-0977-09) from TCGA case TCGA-24-0966, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 78.1 years (28,529 days).
Specimen TCGA-24-0966-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ecdacb7d-6bcc-40a8-a8a7-229100372687.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-24-0966-10A (Blood Derived Normal), aliquot TCGA-24-0966-10A-01W-0421-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/bd19c565-4544-415f-87ed-e9cd87d5f2da

The open-access MAF lists 42 somatic variants for this specimen: 35 protein-altering or splice-affecting, 5 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 34, Silent 5, Frame Shift Ins 1, 3'UTR 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CASK | c.496G>C p.A166P | Missense Mutation (SNP) | VAF 10/82 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1556016347, COSV59372338; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.734G>T p.G245V | Missense Mutation (SNP) | VAF 18/25 reads (72%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121912656, CM010464, CM900209, COSV52666323, COSV52667838, COSV52745465; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ADNP2 | c.2603G>T p.G868V | Missense Mutation (SNP) | VAF 20/26 reads (77%) | SIFT tolerated (0.29); PolyPhen benign (0.06); catalogued as COSV100081001, COSV51541191; called by muse, mutect2, varscan2
- APLP2 | c.182T>C p.M61T | Missense Mutation (SNP) | VAF 25/53 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV53842860; called by muse, mutect2, varscan2
- ARPP21 | c.1345C>T p.P449S | Missense Mutation (SNP) | VAF 10/51 reads (20%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as COSV51803761; called by muse, mutect2, varscan2
- ASB12 | c.272T>A p.V91D | Missense Mutation (SNP) | VAF 48/115 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.94); catalogued as rs1392426671, COSV62857375; called by muse, mutect2, varscan2
- CBLN4 | c.505C>A p.L169I | Missense Mutation (SNP) | VAF 59/144 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.378); catalogued as COSV50353759; called by muse, mutect2, varscan2
- CHERP | c.1210G>A p.G404S | Missense Mutation (SNP) | VAF 35/45 reads (78%) | SIFT tolerated, low confidence (0.16); PolyPhen possibly damaging (0.477); catalogued as rs777719318, COSV52226630; called by muse, mutect2, varscan2
- CREBBP | c.4013T>C p.L1338S | Missense Mutation (SNP) | VAF 14/33 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.763); catalogued as COSV52134459; called by muse, mutect2, varscan2
- DIAPH3 | c.2989T>A p.F997I (on ENST00000400324 / NM_001042517.2; = p.F734I on NM_030932.3) | Missense Mutation (SNP) | VAF 23/114 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.239); catalogued as COSV57376331; called by muse, mutect2, varscan2
- HERC2 | c.1648G>A p.G550R | Missense Mutation (SNP) | VAF 15/46 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.176); catalogued as rs770271788, COSV55340530; called by muse, mutect2, varscan2
- HS3ST2 | c.647C>T p.T216M | Missense Mutation (SNP) | VAF 21/394 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs564701428, COSV54457820; called by muse, mutect2
- IL21R | c.329G>T p.G110V | Missense Mutation (SNP) | VAF 5/99 reads (5%) | SIFT deleterious (0.02); PolyPhen benign (0.406); catalogued as COSV100559798; called by muse, mutect2
- KCNK9 | c.661G>A p.V221M | Missense Mutation (SNP) | VAF 28/55 reads (51%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV57282210; called by muse, mutect2, varscan2
- KPRP | c.28C>T p.R10C | Missense Mutation (SNP) | VAF 55/135 reads (41%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs146340487; called by muse, mutect2, varscan2
- LRRC7 | c.3175G>T p.A1059S (on ENST00000651989 / NM_001370785.2; = p.A1026S on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 28/73 reads (38%) | SIFT tolerated (0.54); PolyPhen benign (0.01); catalogued as COSV50539467; called by muse, mutect2, varscan2
- LRRK1 | c.2383G>A p.D795N | Missense Mutation (SNP) | VAF 18/33 reads (55%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as COSV52621754; called by muse, mutect2, varscan2
- N4BP2 | c.4225G>A p.V1409I | Missense Mutation (SNP) | VAF 40/90 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as rs1266514761, COSV54705016; called by muse, mutect2, varscan2
- NBEA | c.519G>A p.M173I | Missense Mutation (SNP) | VAF 32/36 reads (89%) | SIFT tolerated (0.23); PolyPhen benign (0.006); catalogued as COSV100083463, COSV59807156; called by muse, mutect2, varscan2
- NUTM2F | c.1100C>T p.A367V | Missense Mutation (SNP) | VAF 6/13 reads (46%) | SIFT tolerated (0.29); PolyPhen benign (0.005); catalogued as rs767026006; called by muse, varscan2
- NYAP2 | c.94G>A p.D32N | Missense Mutation (SNP) | VAF 60/152 reads (39%) | SIFT tolerated (0.21); PolyPhen benign (0.203); catalogued as COSV56007554, COSV99798838; called by muse, mutect2, varscan2
- OR4C13 | c.721C>T p.H241Y | Missense Mutation (SNP) | VAF 12/436 reads (3%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as rs1197903149, COSV101634149, COSV101634182; called by muse, mutect2
- PLAAT3 | c.284G>A p.R95Q | Missense Mutation (SNP) | VAF 32/80 reads (40%) | SIFT tolerated (0.55); PolyPhen benign (0.05); catalogued as rs771330726, COSV60312264; called by muse, mutect2, varscan2
- POLR1F | c.947G>C p.S316T | Missense Mutation (SNP) | VAF 93/205 reads (45%) | SIFT tolerated (0.52); PolyPhen benign (0.023); catalogued as COSV55999215; called by muse, mutect2, varscan2
- RELN | c.2357G>A p.R786K | Missense Mutation (SNP) | VAF 23/153 reads (15%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV59022630; called by muse, mutect2, varscan2
- RNF10 | c.782G>A p.S261N | Missense Mutation (SNP) | VAF 61/237 reads (26%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as COSV58047082; called by muse, mutect2, varscan2
- SLC26A4 | c.1813A>G p.I605V | Missense Mutation (SNP) | VAF 132/187 reads (71%) | SIFT tolerated (0.47); PolyPhen benign (0.013); catalogued as rs899919861, COSV55918661; called by muse, mutect2, varscan2
- SLC39A1 | c.233dup p.V79Rfs*13 | Frame Shift Ins (INS) | VAF 6/58 reads (10%) | catalogued as rs763102282; called by pindel, varscan2
- SSU72P8 | c.305C>A p.T102N | Missense Mutation (SNP) | VAF 10/93 reads (11%) | SIFT tolerated (0.34); PolyPhen benign (0.021); catalogued as COSV66361273; called by muse, mutect2, varscan2
- TENM1 | c.6578C>G p.P2193R | Missense Mutation (SNP) | VAF 110/249 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as COSV64438517; called by muse, mutect2, varscan2
- TET1 | c.5118T>A p.H1706Q | Missense Mutation (SNP) | VAF 68/145 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV65387516; called by muse, mutect2, varscan2
- TP53BP2 | c.2866G>C p.D956H (on ENST00000343537 / NM_001031685.3; = p.D827H on NM_005426.2) | Missense Mutation (SNP) | VAF 21/78 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.908); catalogued as COSV59071333; called by muse, mutect2, varscan2
- ZNF236 | c.5236G>A p.G1746R | Missense Mutation (SNP) | VAF 37/42 reads (88%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53493785; called by muse, mutect2, varscan2
- FADS6 | c.1097T>A p.V366E | Missense Mutation (SNP) | VAF 7/7 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); called by muse, mutect2
- SEPTIN7 | c.1099G>C p.E367Q | Missense Mutation (SNP) | VAF 2/13 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); called by muse, mutect2
- CCDC73 | c.1635A>C p.I545= | Silent (SNP) | VAF 51/116 reads (44%) | catalogued as COSV58802147; called by muse, mutect2, varscan2
- FGF13 | c.675G>A p.K225= | Silent (SNP) | VAF 109/273 reads (40%) | catalogued as COSV100263824, COSV59544114, COSV59548696; called by muse, mutect2, varscan2
- KIAA1210 | c.2751C>T p.P917= | Silent (SNP) | VAF 12/126 reads (10%) | called by muse, mutect2
- MYO5C | c.198C>T p.L66= | Silent (SNP) | VAF 38/64 reads (59%) | catalogued as rs371621193; called by muse, mutect2, varscan2
- NOTCH2 | c.2694A>G p.E898= | Silent (SNP) | VAF 46/87 reads (53%) | catalogued as COSV56699638; called by muse, mutect2, varscan2
- C7orf66 | n.124A>G | RNA (SNP) | VAF 81/221 reads (37%) | called by muse, mutect2, varscan2
- MFSD4B | c.*266C>T | 3'UTR (SNP) | VAF 49/54 reads (91%) | catalogued as rs758795099, COSV64349274; called by muse, mutect2, varscan2
